Somatic mutation profile of tumor specimen TCGA-G8-6914-01A (aliquot TCGA-G8-6914-01A-11D-2210-10) from TCGA case TCGA-G8-6914, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 67.3 years (24,569 days).
Specimen TCGA-G8-6914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb51ae5c-cade-4411-995c-3c832dcaee0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6914-14A (Bone Marrow Normal), aliquot TCGA-G8-6914-14A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4432bf4d-33d2-4a43-8961-6c360faf7d5c

The open-access MAF lists 75 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 14, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CARD11 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 33/233 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62717709, COSV62720893; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 79/340 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKR1C1 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs748592020; called by muse, mutect2, varscan2
- ARAP3 | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs536504402; called by muse, mutect2, varscan2
- CACNA1H | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs770827490, COSV61983719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs375309204; called by muse, mutect2, varscan2
- COL22A1 | c.4423C>T p.Q1475* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV57363202; called by muse, mutect2
- CSMD3 | c.6870G>T p.M2290I (on ENST00000297405 / NM_001363185.1; = p.M2186I on NM_052900.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as rs1322971855; called by muse, mutect2, varscan2
- DENND4C | c.4521G>A p.M1507I (on ENST00000434457 / NM_001330640.2; = p.M1458I on NM_017925.7) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1195052851; called by muse, mutect2, varscan2
- DENR | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54889213; called by muse, mutect2
- ERC1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs775535153; called by muse, mutect2, varscan2
- FAM78B | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.629); catalogued as rs138713518, COSV100597733; called by muse, mutect2, varscan2
- FBXO24 | c.1243G>A p.G415S (on ENST00000241071 / NM_033506.3; = p.G453S on NM_012172.5) | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs1296362459; called by muse, mutect2, varscan2
- FNDC4 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs977458631; called by muse, mutect2, varscan2
- GABRG3 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61511256; called by muse, mutect2, varscan2
- IGLV3-1 | c.179A>C p.Q60P | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs375625744; called by muse, varscan2
- KLHL6 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs148924291; called by muse, varscan2
- MASTL | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs753991813; called by muse, mutect2, varscan2
- NFKBIE | c.742C>T p.Q248* (on ENST00000275015; = p.Q109* on NM_004556.3) | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV51487220; called by muse, mutect2
- PCDHA12 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as rs543806401, COSV56503478; called by muse, mutect2, varscan2
- PKD2 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1394711530; called by muse, mutect2, varscan2
- PRDM1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64844667; called by muse, varscan2
- PRDM1 | c.1871T>A p.V624E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100958704; called by muse, mutect2, varscan2
- PSD4 | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs370284646; called by muse, mutect2, varscan2
- SCN7A | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); catalogued as rs746146835, COSV69271782, COSV69273759; called by muse, mutect2, varscan2
- SDCBP2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV60588999; called by muse, mutect2, varscan2
- SLC6A2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54913583; called by muse, mutect2, varscan2
- SPTBN4 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100150967; called by muse, mutect2
- WSCD1 | c.878G>A p.W293* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs267604993, COSV58494729; called by muse, mutect2, varscan2
- ZNF324 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770914514, COSV99543386; called by muse, mutect2, varscan2
- AASDHPPT | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ANKS1A | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ATP13A5 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 38/207 reads (18%) | called by muse, varscan2
- CACNA1E | c.4744del p.R1582Afs*3 | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | called by mutect2, pindel, varscan2
- CAPZA3 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC71 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CHIC1 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNDP1 | c.367A>C p.T123P | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- COL3A1 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA3 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KIF1A | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- KIFC3 | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAMA1 | c.3839G>A p.G1280E | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRIT1 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- LRP2 | c.7827C>G p.D2609E | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- LY75 | c.5020G>A p.V1674I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEF2B | c.676-5_689del p.X226_splice | Splice Site (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel
- NGFR | c.208+1G>A p.X70_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- POLQ | c.4329T>G p.N1443K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PPP3CA | c.1080A>G p.K360= | Splice Region (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- SLC7A5 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TAF6 | c.250T>G p.Y84D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TAP1 | c.2206_2209del p.N736Afs*122 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- TNFSF13B | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- TRIM39 | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TTC39C | c.913C>T p.L305F (on ENST00000317571 / NM_001135993.2; = p.L244F on NM_153211.4) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TTK | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBXN2B | c.85-2A>T p.X29_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- WNK1 | c.955A>T p.M319L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ADGRF5 | c.1119G>A p.L373= | Silent (SNP) | VAF 50/195 reads (26%) | catalogued as rs1283815456; called by muse, mutect2, varscan2
- DOCK5 | c.394C>T p.L132= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs748741297; called by muse, mutect2, varscan2
- GPER1 | c.1020G>A p.E340= | Silent (SNP) | VAF 59/160 reads (37%) | called by muse, mutect2, varscan2
- KLHL6 | c.249C>T p.F83= | Silent (SNP) | VAF 84/176 reads (48%) | called by muse, varscan2
- KLHL7 | c.6A>T p.A2= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- KY | c.36C>T p.I12= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as COSV71016798, COSV71018692; called by muse, mutect2, varscan2
- LRRFIP1 | c.537T>C p.A179= (on ENST00000392000 / NM_001137552.2; = p.A155= on NM_004735.4) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs200278632, COSV99791137; called by muse, mutect2, varscan2
- MYH10 | c.2880C>T p.D960= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs139264814; called by muse, mutect2, varscan2
- OCA2 | c.2088A>T p.A696= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- OVCH1 | c.204G>A p.E68= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- SYNE1 | c.13527A>G p.E4509= (on ENST00000367255 / NM_182961.4; = p.E4438= on NM_033071.3) | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TCEA3 | c.690G>A p.T230= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs752271585, COSV101508315; called by muse, mutect2, varscan2
- XIRP2 | c.1128C>T p.D376= (on ENST00000628543; = p.D551= on NM_152381.6) | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99746188; called by muse, mutect2, varscan2
- ZNF77 | c.876A>G p.G292= | Silent (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.583-1772G>A | Intron (SNP) | VAF 29/57 reads (51%) | catalogued as rs537664586; called by muse, mutect2, varscan2
